Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A187, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A187-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PREOP/POSTOP. Endometrial cancer.

LMP: Postmenopausal.

PROCEDURE: Laparoscopic assisted vaginal hysterectomy, RSO, node sampling, left salpingectomy.

OUTSIDE DIAGNOSIS: No

PRIOR MALIGNANCY: No

CHEMORADIATION THERAPY: No

OTHER DISEASES: No

1CD-0-3

Adenocarcinoma, Endometrioid, NOS 8380/3

Site Code: Endometrium C54.1

12/15/10
RW

**FINAL DIAGNOSIS:**

PART 1: UTERUS WITH RIGHT OVARY AND FALLOPIAN TUBE AND LEFT FALLOPIAN TUBE, LAPAROSCOPIC-ASSISTED VAGINAL HYSTERECTOMY, RIGHT SALPINGO-OOPHORECTOMY AND LEFT SALPINGECTOMY (70 GRAMS) -

- A. ENDOMETRIUM WITH POLYPOID MODERATELY DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA INVOLVING ABOUT 65% OF ENDOMETRIAL SURFACE AND PENETRATING UP TO 80% OF MYOMETRIAL THICKNESS (1C), (see comment).
- B. UNINVOLVED ENDOMETRIUM IN PROLIFERATIVE PATTERN.
- C. CHRONIC CYSTIC CERVICITIS WITH SQUAMOUS METAPLASIA AND PARAKERATOSIS.
- D. RIGHT OVARY WITH SEROSAL ADHESIONS AND EPITHELIAL INCLUSIONS, NO TUMOR IS SEEN.
- E. RIGHT FALLOPIAN TUBE, NO TUMOR SEEN.
- F. LEFT FALLOPIAN TUBE, NO TUMOR SEEN.

PART 2: LYMPH NODE, LEFT PELVIC, BIOPSY -
TWO LYMPH NODES, FREE OF TUMOR (0/2).PART 3: LYMPH NODES, RIGHT PELVIC, BIOPSY -
TWO LYMPH NODES, FREE OF TUMOR (0/2).PART 4: LYMPH NODES, LEFT PERIAORTIC, BIOPSY -
THREE LYMPH NODES, FREE OF TUMOR (0/3).PART 5: LYMPH NODE, RIGHT PERIAORTIC, BIOPSY -
NO LYMPH NODE OR TUMOR IS SEEN.PART 6: OMENTUM, BIOPSY -
OMENTUM WITH INFLAMMATION AND FIBROUS ADHESIONS, NO TUMOR SEEN.**COMMENT:**

This endometrioid adenocarcinoma represents FIGO stage IB. The peritoneal cytology

is negative for malignant cells.

The patient's previous endometrial biopsy with endometrioid adenocarcinoma

noted.

The results of immunohistochemical stains for D2-40 and CD31, support the above diagnosis (see microscopic description).

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

TUMOR TYPE:**SPECIMENS**

Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE:

Moderately differentiated

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 4.8 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 90 %, Posterior endomyometrium: 40 %

Greater than or equal to 1/2 thickness of myometrium

DEPTH OF INVASION:

No

ANGIOLYMPHATIC INVASION:

Number of lymph nodes positive:: 0

LYMPH NODES POSITIVE:

Total number of lymph nodes examined: 7

LYMPH NODES EXAMINED:

pT1b

T STAGE, PATHOLOGIC:

pN0

N STAGE, PATHOLOGIC:

Not applicable

M STAGE, PATHOLOGIC:**FIGO STAGE:**

IB

Source: NCI Genomic Data Commons file 93e4f752-e454-498c-85d4-d1647a4d1302 (TCGA-BG-A187.CB8E915A-CE5D-4181-9303-22BD8CBCB80D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).